Somatic mutation profile of tumor specimen 0DM4XJ from CCDI case PBBZXZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 9.5 years (3,473 days).
Specimen 0DM4XJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73db8eac-8de3-4136-a1bb-52a32918e840.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM4X5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/508f3900-a557-4878-be4b-61a26ad7c54e

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 58/1790 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 48/1844 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- PKDCC | c.1396G>C p.G466R | Missense Mutation (SNP) | VAF 28/764 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TAF4 | c.3158_3168dup p.R1057Kfs*15 | Frame Shift Ins (INS) | VAF 229/730 reads (31%) | called by mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 12/281 reads (4%) | called by muse, mutect2
- GALNT14 | c.129+12769C>T | Intron (SNP) | VAF 28/820 reads (3%) | called by muse, mutect2
- SMOC1 | c.-60G>T | 5'UTR (SNP) | VAF 4/89 reads (4%) | called by muse, mutect2
